Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A8NJ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A8NJ-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 1
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE:

VERIFIED BY:

year-old male with difficulty swallowing, positive esophageal carcinoma.
Esophageal cancer. Transhiatal esophagectomy.

PROCEDURE:

VERIFIED BY:

1. "Thoracic esophagus". A 9.5 cm length of esophagus in continuity with a 9.0 x 2.0 cm proximal stomach. Located 5.0 cm from the proximal margin and 2.0 cm from the distal margin is a 5.5 x 4.0 cm polypoid mass. Sectioning reveals the mass penetrates to a depth of 1.0 cm and distorts the exterior of the specimen. The mass extends across the GE junction and into the proximal stomach. The mucosa extending for 6 cm proximal to the GE junction is a band of salmon colored mucosa. The proximal most 2 cm of esophageal mucosa is pink, wrinkled and unremarkable. Several lymph nodes are identified in the periesophageal adipose tissue, the largest firm, white and 1.5 cm.
1A-C, 1D-F. Cross section through lesion to include distal margin inked blue, each trisected. (1ss each). Deepest point of invasion in 1B and 1E.
1G. Proximal esophagus inked blue incontinuity with salmon colored mucosa.
1H. Largest lymph node bisected.
1I. Possible lymph nodes.
1J. Possible lymph nodes.
2. "#8 periesophageal ln". A 1.7 x 1.1 x 1.0 cm black lymph node. Cut surfaces reveal a black lymph node expanded by uniform, white tissue.
3. "Cervical esophageal margin". A 2.2 cm length of tubular esophagus 2.0 cm in diameter. The shave margin immediately subjacent to the staple line is submitted in one cassette.

PROCEDURE:

VERIFIED BY:

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal third
C15.5
11/17/14

ESOPHAGEAL, CARDIAC AND GASTROESOPHAGEAL JUNCTION CARCINOMA:

Type of carcinoma: Adenocarcinoma

If adenocarcinoma, is it arising in: Barrett's mucosa

Depth of invasion: Adventitia

Number of positive lymph nodes: 3/10

Extranodal metastasis: Unknown

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:
BIRTHDATE:

PATIENT NBR:

PAGE #: 2
SEX: M
ADM DATE:

ACCESSION:

OPER DATE:

REQ DOC:

Pattern of invasion: Infiltrative
Esophageal and gastric resection margins involved: No
Deep resection margin involved: No
TNM classification: T3N1Mx

PROCEDURE:

VERIFIED BY:

1. Distal esophagus and proximal stomach, transhiatal esophagectomy: Invasive adenocarcinoma arising in the background of Barrett's mucosa. The neoplasm invades through the esophageal wall to the adventitia and closely approximates the inked soft tissue margin. Distal gastric margins negative for neoplasm. Three esophageal lymph nodes positive for carcinoma. See template.
2. #8 periesophageal lymph node, excision: Positive for adenocarcinoma.
3. Esophagus, cervical margin: Negative for neoplasm.

M.D.

I, _____, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Code:

** END OF PREVIOUS DIAGNOSIS INQUIRY **

IHPAA Discrepancy		

Source: NCI Genomic Data Commons file b2b6052a-ed0c-47a9-bf59-a519c559ea4c (TCGA-L5-A8NJ.8ACA1817-3BB1-4608-B95D-28357676DB55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).